Somatic mutation profile of tumor specimen MP2PRT-PAWCVM-TMP1-B (aliquot MP2PRT-PAWCVM-TMP1-B-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAWCVM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (999 days).
Specimen MP2PRT-PAWCVM-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56d35521-7fc9-461b-97eb-0f790b6fb435.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCVM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCVM-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/775fad45-bb96-4fc3-8900-d579e69e6f0d

The open-access MAF lists 68 somatic variants for this specimen: 54 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 11, Nonsense Mutation 2, RNA 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR7A3 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 160/448 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.422); catalogued as COSV100853826; called by muse, mutect2, varscan2
- ANKRD36 | c.3189G>C p.L1063F | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.991); catalogued as COSV101347496; called by muse, mutect2
- ARHGEF9 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 103/362 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99491325; called by muse, mutect2, varscan2
- ASXL3 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV52464571; called by muse, mutect2, varscan2
- B4GALT6 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 24/425 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as COSV52704581; called by muse, mutect2
- CAMK2A | c.1324G>A p.G442S (on ENST00000348628 / NM_171825.2; = p.G453S on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 230/725 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); catalogued as rs772552968; called by muse, mutect2, varscan2
- CCNB1 | c.603G>C p.M201I | Missense Mutation (SNP) | VAF 64/527 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV56509983; called by muse, mutect2, varscan2
- CDH19 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as COSV100051925; called by muse, mutect2, varscan2
- CIAO3 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 179/493 reads (36%) | catalogued as rs1321911078; called by muse, mutect2, varscan2
- CNOT1 | c.1347G>C p.K449N | Missense Mutation (SNP) | VAF 22/379 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV57764410; called by muse, mutect2
- CNTN4 | c.1768G>C p.D590H | Missense Mutation (SNP) | VAF 54/473 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV61870752, COSV61873251; called by muse, mutect2, varscan2
- DNAH3 | c.4769C>T p.S1590L | Missense Mutation (SNP) | VAF 44/532 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200739265; called by muse, mutect2
- FNDC1 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 62/662 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.15); catalogued as rs746337128; called by muse, mutect2
- FSTL1 | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 25/328 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV55232876; called by muse, mutect2
- H3C11 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 137/424 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV58899154; called by muse, mutect2, varscan2
- HERC2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 42/672 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99872808; called by muse, mutect2
- ITGA7 | c.2327C>T p.A776V (on ENST00000555728; = p.A732V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/447 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs368879643, COSV57691178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1549L | c.1747G>A p.E583K (on ENST00000321505; = p.E880K on NM_012194.3) | Missense Mutation (SNP) | VAF 247/624 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV55781238; called by muse, mutect2, varscan2
- LTF | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 26/612 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1394625677, COSV51607082; called by muse, mutect2
- MOK | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 331/692 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375778084; called by muse, mutect2, varscan2
- MTARC2 | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 37/522 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63765463; called by muse, mutect2
- MTO1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 99/456 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770260720; called by muse, mutect2, varscan2
- NAV3 | c.3734C>T p.S1245L | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57077399; called by muse, mutect2
- NOB1 | c.648G>C p.Q216H | Missense Mutation (SNP) | VAF 272/768 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs749007038; called by muse, varscan2
- OR8H3 | c.221A>T p.Y74F | Missense Mutation (SNP) | VAF 65/784 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57911639; called by muse, mutect2
- PABPC5 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs1412882405; called by muse, mutect2
- PCK1 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 147/422 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs373529977; called by muse, mutect2, varscan2
- POLA1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751442544; called by muse, mutect2, varscan2
- PRR27 | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 39/678 reads (6%) | catalogued as COSV100748877; called by muse, mutect2
- RIMBP2 | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 46/854 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs538642944, COSV55464306; called by muse, mutect2
- RMND5A | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 75/240 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.076); catalogued as rs1351442390; called by muse, varscan2
- SYCP2L | c.1746G>C p.K582N | Missense Mutation (SNP) | VAF 120/286 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV99304602; called by muse, mutect2, varscan2
- TAOK3 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 103/290 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV66824923; called by muse, mutect2, varscan2
- TRAP1 | c.2047G>C p.V683L | Missense Mutation (SNP) | VAF 158/434 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as rs1421990518; called by muse, varscan2
- ZNF324B | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 215/662 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs748178828; called by muse, mutect2, varscan2
- ZNF808 | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 27/444 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs781451094, COSV63120263; called by muse, mutect2
- DZIP1 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); called by muse, mutect2
- FAT3 | c.3600C>G p.I1200M | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2
- IDI1 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 109/310 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714681 GTCTCTCGCACAG>TCCC | Missense Mutation (DEL) | VAF 76/229 reads (33%) | called by pindel, varscan2*
- LACTB | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 126/350 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MED1 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 108/335 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- OR8H2 | c.221A>T p.Y74F | Missense Mutation (SNP) | VAF 219/512 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFKL | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 270/606 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PITX2 | c.576G>C p.K192N (on ENST00000354925 / NM_001204397.1; = p.K199N on NM_000325.6) | Missense Mutation (SNP) | VAF 48/640 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PLCB4 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PPARGC1A | c.1076G>C p.S359T | Missense Mutation (SNP) | VAF 38/560 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2
- PPP3CC | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 156/298 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMD12 | c.506G>C p.R169T | Missense Mutation (SNP) | VAF 157/458 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEC24A | c.2364G>C p.Q788H | Missense Mutation (SNP) | VAF 141/452 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- U2SURP | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF248 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 170/528 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF404 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2
- ZNF468 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 145/426 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- CERT1 | c.252C>T p.L84= | Silent (SNP) | VAF 80/1122 reads (7%) | catalogued as COSV54033728; called by muse, mutect2
- DNMBP | c.1275G>A p.Q425= | Silent (SNP) | VAF 50/608 reads (8%) | called by muse, mutect2
- EPHA4 | c.2091C>T p.I697= | Silent (SNP) | VAF 83/290 reads (29%) | catalogued as COSV56027123; called by muse, mutect2, varscan2
- MB21D2 | c.1134C>T p.F378= | Silent (SNP) | VAF 119/564 reads (21%) | catalogued as rs748456390, COSV66664585; called by muse, mutect2, varscan2
- NAALAD2 | c.732G>A p.Q244= | Silent (SNP) | VAF 171/435 reads (39%) | catalogued as COSV100428808, COSV58961840; called by muse, mutect2, varscan2
- PODN | c.1254G>A p.A418= (on ENST00000395871; = p.A370= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 273/782 reads (35%) | catalogued as rs370467120; called by muse, mutect2, varscan2
- SLC19A3 | c.903C>A p.I301= | Silent (SNP) | VAF 275/530 reads (52%) | catalogued as COSV99295988; called by muse, mutect2, varscan2
- SSC5D | c.519G>A p.K173= | Silent (SNP) | VAF 52/376 reads (14%) | called by muse, mutect2, varscan2
- ST14 | c.2118C>T p.F706= | Silent (SNP) | VAF 299/841 reads (36%) | called by muse, mutect2, varscan2
- TMC2 | c.636G>A p.L212= | Silent (SNP) | VAF 37/475 reads (8%) | catalogued as COSV62659524; called by muse, mutect2
- TPM1 | c.87G>A p.K29= | Silent (SNP) | VAF 148/433 reads (34%) | catalogued as rs530234301, COSV51266775; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLEC19A | chr16:19309071 G>C | 3'Flank (SNP) | VAF 31/406 reads (8%) | called by muse, mutect2
- IFNL4 | c.224-80G>C | Intron (SNP) | VAF 82/1170 reads (7%) | called by muse, mutect2
- NBPF25P | n.1932G>T | RNA (SNP) | VAF 18/391 reads (5%) | called by muse, mutect2
